Somatic mutation profile of tumor specimen 0DKV58 from CCDI case PBBXTS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Overlapping lesion of lung; Age at diagnosis: 0.3 years (103 days).
Specimen 0DKV58: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d761111c-769b-411e-b52d-a331902c4911.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKV57 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c35e137-ad6a-4f90-94c0-75e8ebf4535c

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Intron 1, Splice Site 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDS5B | c.1204-1G>T p.X402_splice | Splice Site (SNP) | VAF 64/890 reads (7%) | catalogued as COSV59732171; called by muse, mutect2
- RABEP2 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 190/404 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as rs1400721271, COSV100707141; called by muse, varscan2
- IRAK1 | c.216C>A p.P72= | Silent (SNP) | VAF 128/355 reads (36%) | called by muse, mutect2, varscan2
- KHDC1L | c.261C>T p.C87= | Silent (SNP) | VAF 36/867 reads (4%) | catalogued as rs1013188309; called by muse, mutect2
- PUS10 | c.897G>A p.R299= | Silent (SNP) | VAF 270/683 reads (40%) | catalogued as COSV57450999; called by muse, mutect2, varscan2
- CFAP70 | c.3286-87G>A | Intron (SNP) | VAF 3/42 reads (7%) | catalogued as rs1168297833; called by muse, mutect2
